Somatic mutation profile of tumor specimen TCGA-ET-A25R-01A (aliquot TCGA-ET-A25R-01A-11D-A17V-08) from TCGA case TCGA-ET-A25R, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.6 years (18,863 days).
Specimen TCGA-ET-A25R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc8307f1-cd47-4f40-9621-c478eceb31a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A25R-10A (Blood Derived Normal), aliquot TCGA-ET-A25R-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d450faa-7a53-4d7d-b704-7b587a151413

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADH7 | c.740T>A p.V247E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52922487; called by muse, mutect2, varscan2
- MESP1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as COSV100262284; called by muse, mutect2
- TMCC1 | c.1388T>A p.L463Q (on ENST00000393238 / NM_001349268.2; = p.L139Q on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61442289; called by muse, mutect2
- TNRC6B | c.4463G>A p.G1488D (on ENST00000454349 / NM_001162501.2; = p.G1378D on NM_015088.3) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57304861; called by muse, mutect2, varscan2
- DHX30 | c.667del p.R223Gfs*7 (on ENST00000445061 / NM_138615.3; = p.R184Gfs*7 on NM_014966.3) | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.6033C>T p.V2011= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV67992733; called by muse, mutect2
- ANKRD35 | c.1104C>T p.G368= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV62911283; called by muse, mutect2, varscan2
- ITGA8 | c.2067T>C p.F689= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV65233970; called by muse, mutect2, varscan2
